Somatic mutation profile of tumor specimen TCGA-G2-AA3B-01A (aliquot TCGA-G2-AA3B-01A-11D-A391-08) from TCGA case TCGA-G2-AA3B, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.7 years (27,646 days).
Specimen TCGA-G2-AA3B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd807421-e472-4ca0-a153-0429639fccd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-AA3B-10A (Blood Derived Normal), aliquot TCGA-G2-AA3B-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d158ce0-7d4e-4d09-97af-e9f3c6ebbe3a

The open-access MAF lists 822 somatic variants for this specimen: 607 protein-altering or splice-affecting, 189 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 533, Silent 189, Nonsense Mutation 43, Splice Site 13, Intron 10, RNA 8, Frame Shift Del 7, Splice Region 6, 3'UTR 4, 5'UTR 2, Nonstop Mutation 2, 5'Flank 2.

Variants (750 of 822; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.4148C>G p.S1383* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs80357071, CM1413159, COSV100524264; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 37/44 reads (84%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.6545C>G p.S2182C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV66064982; called by muse, mutect2, varscan2
- ABCA4 | c.6769G>T p.D2257Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV64672419; called by muse, mutect2, varscan2
- ABCA4 | c.6480-1G>C p.X2160_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as CS161766, COSV64672423; called by muse, mutect2, varscan2
- ABCA4 | c.2248C>A p.L750M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1220683379, COSV64672429; called by muse, mutect2, varscan2
- ABCA8 | c.4082T>G p.L1361* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99285897; called by muse, mutect2, varscan2
- AC018630.4 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV57392000; called by muse, mutect2, varscan2
- AC024598.1 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); catalogued as COSV60823856; called by muse, mutect2, varscan2
- ACSM3 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as COSV55500569; called by muse, mutect2, varscan2
- ACTG1 | c.467G>C p.G156A | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59509822, COSV59509870; called by muse, mutect2
- ADAM2 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV55865564, COSV99697377; called by muse, mutect2, varscan2
- ADAM21 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99961053; called by mutect2, varscan2
- ADAMTS12 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV61259263; called by muse, mutect2
- ADAMTS15 | c.1531A>C p.N511H | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54504183; called by muse, mutect2, varscan2
- ADGRG2 | c.356C>G p.S119* (on ENST00000379869 / NM_001079858.3; = p.S116* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 13/285 reads (5%) | catalogued as COSV100492288; called by muse, mutect2
- AFDN | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as rs754362514, COSV60041147; called by muse, mutect2, varscan2
- AFDN | c.5404C>T p.Q1802* (on ENST00000447894 / NM_001366320.1; = p.Q1721* on NM_001207008.1) | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs1467379849, COSV100653048; called by muse, mutect2, varscan2
- AFF4 | c.3042C>G p.F1014L | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54793063; called by muse, mutect2, varscan2
- AFF4 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54793071; called by muse, mutect2, varscan2
- AHDC1 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55937586; called by muse, mutect2, varscan2
- AKAP6 | c.5276C>G p.S1759C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55209011; called by muse, mutect2, varscan2
- AKR1B15 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV71151346, COSV71152166; called by muse, mutect2, varscan2
- AKR1D1 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54336902, COSV54339308; called by muse, mutect2, varscan2
- ALDH16A1 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs143931782; called by muse, mutect2, varscan2
- ALPK1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779895727, COSV51583461; called by muse, mutect2
- ALPK2 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100864782, COSV64491562; called by muse, mutect2, varscan2
- AMBRA1 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54051060; called by muse, mutect2, varscan2
- ANAPC5 | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs147306166; called by muse, mutect2, varscan2
- ANK1 | c.2475C>G p.I825M | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as COSV55877254; called by muse, mutect2, varscan2
- ANKRD12 | c.2593G>C p.D865H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV50820083, COSV50820999; called by muse, mutect2, varscan2
- AP1B1 | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0.026); catalogued as COSV58015806; called by muse, mutect2, varscan2
- AP2B1 | c.1521G>C p.L507F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51998070; called by muse, mutect2, varscan2
- APLNR | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as COSV57241900; called by muse, mutect2, varscan2
- ARHGAP33 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as COSV50120424; called by muse, mutect2, varscan2
- ARHGAP8 | c.690-2A>C p.X230_splice (on ENST00000389774 / NM_001017526.1; = p.X199_splice on NM_181335.3) | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV61232360; called by muse, mutect2, varscan2
- ARHGEF3 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56324836; called by muse, mutect2, varscan2
- ARHGEF6 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV51688881; called by muse, mutect2, varscan2
- ARHGEF7 | c.2356G>C p.E786Q (on ENST00000646102 / NM_001354046.1; = p.E570Q on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV54540830; called by muse, mutect2, varscan2
- ARID4A | c.2695A>T p.N899Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV62162842; called by mutect2, varscan2
- ARMC4 | c.3134G>C p.*1045Sext*13 | Nonstop Mutation (SNP) | VAF 39/103 reads (38%) | catalogued as rs926736331, COSV100536899, COSV100537436, COSV59463328; called by muse, varscan2
- ASAP2 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53005683; called by muse, mutect2, varscan2
- ASIC4 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV61731389; called by muse, mutect2, varscan2
- ASPM | c.6392A>C p.Q2131P | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV54127346; called by muse, mutect2
- ASXL2 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55455938; called by muse, mutect2, varscan2
- ATG4D | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs757684533, COSV58762274; called by muse, mutect2, varscan2
- ATM | c.6490G>C p.E2164Q | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1317619286, COSV53730905, COSV53774759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A1 | c.704A>C p.N235T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV55190514; called by muse, mutect2, varscan2
- ATP6V1A | c.1738A>C p.K580Q | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV56361526; called by muse, mutect2, varscan2
- ATP7B | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as CM133398, COSV54436711; called by muse, mutect2
- ATP8B1 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 82/104 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV52173981, COSV52174182; called by muse, mutect2, varscan2
- ATPAF1 | c.622G>C p.E208Q (on ENST00000574428; = p.E231Q on NM_022745.4) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61304604; called by muse, mutect2, varscan2
- AUTS2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV61390842; called by muse, mutect2, varscan2
- AXDND1 | c.3019T>C p.S1007P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62640995; called by muse, mutect2, varscan2
- BCAN | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1476862418, COSV61256089; called by muse, mutect2, varscan2
- BCAR3 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs768251210, COSV53073656; called by muse, mutect2, varscan2
- BCL2L2-PABPN1 | c.1079C>T p.S360L (on ENST00000678502; = p.S328L on NM_001199864.2) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.018); catalogued as COSV53729359; called by muse, mutect2, varscan2
- BRCA2 | c.3265C>G p.Q1089E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.167); catalogued as CM110365, COSV66450960; called by muse, mutect2, varscan2
- BRD2 | c.1518G>C p.E506D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.306); catalogued as COSV66372832; called by muse, mutect2
- BRIP1 | c.3521G>C p.R1174T | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.199); catalogued as rs786202662, COSV51996620; ClinVar: uncertain significance; called by muse, mutect2
- C14orf28 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.969); catalogued as COSV57333085; called by muse, mutect2, varscan2
- C1S | c.1652C>A p.P551Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100196575; called by muse, mutect2
- C2orf76 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV100601710; called by muse, mutect2
- C3 | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV55570828; called by muse, mutect2
- C6 | c.2331G>C p.Q777H | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV54707628; called by muse, mutect2
- CABLES2 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 13/170 reads (8%) | catalogued as COSV99653178; called by muse, mutect2
- CACNG1 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV56826240; called by muse, mutect2, varscan2
- CACYBP | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV62881126; called by muse, mutect2, varscan2
- CAMK1 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56538157; called by muse, mutect2, varscan2
- CASP8AP2 | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV52748849, COSV99387089; called by muse, mutect2, varscan2
- CCDC117 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99968873; called by muse, mutect2
- CCDC30 | c.530G>A p.R177Q (on ENST00000340612; = p.R134Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs771159252, COSV59605287; called by muse, mutect2
- CCDC73 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV58796851; called by muse, mutect2, varscan2
- CCDC87 | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1236687660, COSV59578676; called by muse, mutect2, varscan2
- CCDC88A | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV55058868; called by muse, mutect2, varscan2
- CCNP | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1336128371, COSV99695873; called by muse, mutect2
- CCT6A | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51905041; called by muse, mutect2, varscan2
- CDC20 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs759844021, COSV60521885; called by muse, mutect2, varscan2
- CDC34 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99198838; called by muse, mutect2, varscan2
- CDC40 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.3); catalogued as rs1177141948, COSV100309166, COSV57008805; called by muse, mutect2, varscan2
- CDC73 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100813990, COSV66465939; called by muse, mutect2, varscan2
- CDH10 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 59/412 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52575394; called by muse, mutect2, varscan2
- CDH11 | c.1396C>G p.R466G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV51756103, COSV51770009, COSV99216980; called by muse, mutect2, varscan2
- CDH2 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV52275344; called by muse, mutect2, varscan2
- CDK11B | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58337508; called by muse, mutect2, varscan2
- CDK5R1 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs761983951, COSV57830692; called by muse, mutect2, varscan2
- CEP250 | c.4623G>C p.Q1541H | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61168942; called by muse, mutect2
- CEP57 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV57687764; called by muse, mutect2, varscan2
- CEP68 | c.2194C>G p.L732V | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs760928907, COSV53124090; called by muse, mutect2, varscan2
- CFAP43 | c.3353G>A p.R1118Q | Missense Mutation (SNP) | VAF 133/242 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs772172286, COSV63852570; called by muse, mutect2, varscan2
- CFAP70 | c.2516C>T p.S839L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV60282008; called by muse, mutect2, varscan2
- CFAP74 | c.4270G>A p.V1424M | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1281356386, COSV60586471; called by muse, mutect2, varscan2
- CHD6 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58555519; called by muse, mutect2, varscan2
- CHD9 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV68297561; called by muse, mutect2, varscan2
- CHST9 | c.1170del p.K391Nfs*20 | Frame Shift Del (DEL) | VAF 88/196 reads (45%) | catalogued as COSV52433281; called by mutect2, pindel, varscan2
- CIT | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55864180; called by muse, mutect2, varscan2
- CLEC7A | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV53721746; called by muse, mutect2, varscan2
- CLIP1 | c.3864G>C p.K1288N (on ENST00000620786 / NM_001247997.1; = p.K1277N on NM_002956.2) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56799552; called by muse, mutect2, varscan2
- CNTN2 | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.496); catalogued as COSV59349087; called by muse, mutect2, varscan2
- COLEC12 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | catalogued as COSV101232078; called by muse, mutect2
- COPG1 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV59113174; called by muse, mutect2, varscan2
- CPA4 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55982748; called by muse, mutect2, varscan2
- CPA5 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs782013864, COSV62569194; called by muse, mutect2, varscan2
- CPQ | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV55141197; called by muse, mutect2, varscan2
- CPS1 | c.1549+1G>C p.X517_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as CS114433, COSV51805789; called by muse, mutect2, varscan2
- CREB5 | c.172C>G p.Q58E (on ENST00000357727 / NM_182898.4; = p.Q51E on NM_004904.3) | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV63218738; called by muse, mutect2, varscan2
- CREBRF | c.1491G>C p.Q497H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV51632174; called by muse, mutect2, varscan2
- CRYBB1 | c.134C>G p.P45R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV53232834; called by muse, mutect2, varscan2
- CSF3R | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV58963479; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.862); catalogued as COSV65675294; called by muse, mutect2, varscan2
- CSMD3 | c.10052C>G p.S3351C (on ENST00000297405 / NM_001363185.1; = p.S3182C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV52137625, COSV99838503; called by muse, mutect2
- CSMD3 | c.2413C>T p.H805Y (on ENST00000297405 / NM_001363185.1; = p.H701Y on NM_052900.3) | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV52137642, COSV52234901; called by muse, mutect2, varscan2
- CTRL | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV52122902; called by muse, mutect2
- CUBN | c.7572G>C p.E2524D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as COSV64711466; called by muse, mutect2, varscan2
- CUL9 | c.7305G>C p.Q2435H | Missense Mutation (SNP) | VAF 146/243 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52726907; called by muse, mutect2, varscan2
- CXXC1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1464344742, COSV53273717; called by muse, mutect2, varscan2
- CYLC1 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61411007; called by muse, mutect2
- CYP17A1 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64004822, COSV64005040; called by muse, mutect2, varscan2
- CYP2C18 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV53670927; called by muse, mutect2, varscan2
- DAPK3 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV100009697; called by muse, mutect2
- DCC | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV59093511; called by muse, mutect2
- DCP1B | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV54968085; called by muse, mutect2, varscan2
- DDX11 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52500826, COSV52501752; called by muse, mutect2, varscan2
- DDX18 | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV54305917; called by muse, mutect2, varscan2
- DDX18 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54305925; called by muse, mutect2, varscan2
- DDX31 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV60134846; called by muse, mutect2, varscan2
- DEDD | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.25); catalogued as COSV63501331; called by muse, mutect2, varscan2
- DENND4B | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304367478, COSV63407985; called by muse, mutect2
- DGKG | c.1919G>A p.C640Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53962945; called by muse, mutect2, varscan2
- DIP2C | c.2038A>G p.M680V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1319242074, COSV55151455; called by muse, mutect2, varscan2
- DISP3 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV53823948; called by muse, mutect2, varscan2
- DLG5 | c.5042C>A p.S1681* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100967516; called by muse, mutect2, varscan2
- DLGAP4 | c.2271G>C p.Q757H (on ENST00000339266 / NM_001365621.1; = p.Q754H on NM_014902.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV59415970, COSV59417039; called by muse, mutect2, varscan2
- DLGAP4 | c.2491G>C p.E831Q (on ENST00000339266 / NM_001365621.1; = p.E828Q on NM_014902.6) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1161607774, COSV59415988, COSV59423554; called by muse, mutect2, varscan2
- DMD | c.10681G>C p.E3561Q | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58900506; called by muse, mutect2, varscan2
- DMD | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.279); catalogued as CM132403, COSV55861405, COSV55870388; called by muse, mutect2
- DNAH10 | c.305G>C p.R102P (on ENST00000409039; = p.R41P on NM_207437.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV101292293, COSV68988181; called by muse, mutect2, varscan2
- DNAH11 | c.2100C>G p.F700L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV60947947; called by muse, mutect2, varscan2
- DNAH5 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 30/579 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV54213848; called by muse, mutect2
- DNAH8 | c.11051C>T p.A3684V | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749482996, COSV59434580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB4 | c.1010C>G p.S337* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100883462, COSV100883494; called by muse, mutect2
- DNAJC1 | c.1230G>C p.M410I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65409994; called by muse, mutect2, varscan2
- DNAJC13 | c.3170A>G p.Y1057C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53447940; called by muse, mutect2, varscan2
- DNAJC14 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57912554; called by muse, mutect2, varscan2
- DOCK6 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as rs750382885, COSV52948765; called by muse, mutect2, varscan2
- DOK1 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.392); catalogued as COSV51206627; called by muse, mutect2, varscan2
- DRG1 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV58918332; called by muse, mutect2, varscan2
- DST | c.3034C>G p.L1012V (on ENST00000361203 / NM_001374722.1; = p.L686V on NM_001723.6) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55005271; called by muse, mutect2, varscan2
- DYNC2H1 | c.9644C>G p.S3215C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV62090123; called by muse, mutect2, varscan2
- E2F8 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100001761, COSV51462539; called by muse, mutect2, varscan2
- EDA | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); catalogued as CM152375, COSV58876364; called by muse, mutect2, varscan2
- EHBP1 | c.410A>T p.K137I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50417707; called by muse, mutect2, varscan2
- EHHADH | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV51628883; called by muse, mutect2, varscan2
- ELL2 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV52981748; called by muse, mutect2, varscan2
- ELMO3 | c.1455C>G p.F485L (on ENST00000652269; = p.F432L on NM_024712.5) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV58526862; called by muse, mutect2, varscan2
- EPC1 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53924292; called by muse, mutect2, varscan2
- EPG5 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as COSV56347232; called by muse, mutect2, varscan2
- EPHB2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 15/100 reads (15%) | catalogued as COSV101007112; called by muse, mutect2, varscan2
- ERICH3 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV58602787; called by muse, mutect2
- EXOC3 | c.1564C>G p.P522A | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV59266147; called by muse, mutect2, varscan2
- EXOC4 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 70/101 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as rs1415153994, COSV54090364; called by muse, mutect2, varscan2
- EZHIP | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV100539844, COSV57955577; called by muse, mutect2, varscan2
- F8 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV100811561; called by muse, mutect2
- FAM111B | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as rs1238897626, COSV100639295, COSV100639383; called by muse, mutect2, varscan2
- FAM120A | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52903016; called by muse, mutect2, varscan2
- FAM120B | c.1860C>A p.F620L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.042); catalogued as COSV53002570; called by muse, mutect2, varscan2
- FAM162A | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV51657644; called by muse, mutect2
- FAM186B | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV57720984; called by muse, mutect2, varscan2
- FANCA | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as CM970493, COSV59796069; called by muse, mutect2, varscan2
- FANCI | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.724); catalogued as COSV55525002; called by muse, mutect2
- FASTKD1 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs769679329, COSV70006749; called by muse, mutect2, varscan2
- FAT1 | c.11872C>T p.Q3958* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV71676205; called by muse, mutect2, varscan2
- FBN2 | c.8383G>T p.E2795* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99327827; called by muse, mutect2, varscan2
- FBXO4 | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55851699; called by muse, mutect2, varscan2
- FBXO42 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as COSV100981816; called by muse, mutect2, varscan2
- FDPS | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63114149; called by muse, mutect2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as rs144178676; called by mutect2, varscan2
- FILIP1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs142185679, COSV52725789; called by muse, mutect2, varscan2
- FLG | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as rs147854910, COSV64239023; called by muse, mutect2, varscan2
- FLT3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.341); catalogued as COSV54048641; called by muse, mutect2, varscan2
- FNDC3B | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61039641; called by muse, mutect2, varscan2
- FOXN1 | c.1568G>C p.G523A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56881102, COSV99881333; called by muse, mutect2, varscan2
- FRAS1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53599245; called by muse, varscan2
- FYB1 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as COSV60943464; called by muse, varscan2
- FZD6 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV62470990; called by muse, mutect2, varscan2
- GABRQ | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV64781367; called by muse, mutect2, varscan2
- GAK | c.3612G>A p.M1204I | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58503669, COSV58510516; called by muse, mutect2, varscan2
- GALNTL5 | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67179643, COSV67179887; called by muse, mutect2, varscan2
- GAR1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV56993156; called by muse, mutect2, varscan2
- GATB | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199617607, COSV56129475; called by muse, mutect2, varscan2
- GBX2 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100103545; called by muse, mutect2, varscan2
- GFOD1 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 66/79 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV64954475; called by muse, mutect2, varscan2
- GGTLC1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV53846948, COSV53847908; called by muse, mutect2, varscan2
- GLP1R | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV64714658; called by muse, mutect2, varscan2
- GOLGB1 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV61463526; called by muse, mutect2, varscan2
- GOLM2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55462540; called by muse, mutect2, varscan2
- GP1BA | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CM156802, COSV56698919; called by muse, mutect2, varscan2
- GPR141 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs780929544, COSV57731790; called by muse, mutect2, varscan2
- GPR156 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV59938854; called by muse, mutect2, varscan2
- GPR20 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs1335640573, COSV66684144; called by muse, mutect2
- GSTM1 | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 56/68 reads (82%) | catalogued as COSV100564417; called by muse, mutect2, varscan2
- GTF2E1 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV52203772; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100736431; called by mutect2, varscan2
- GYS2 | c.1309-1G>A p.X437_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV53921638; called by mutect2, varscan2
- H4C5 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV63486394, COSV63487102; called by muse, mutect2, varscan2
- HAUS5 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV52547307; called by muse, mutect2, varscan2
- HCAR2 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61024642; called by muse, mutect2, varscan2
- HDX | c.796T>C p.F266L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52974581; called by mutect2, varscan2
- HECTD1 | c.2593C>G p.Q865E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV65991181; called by muse, mutect2, varscan2
- HERC1 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71246867; called by muse, mutect2, varscan2
- HFM1 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54021361, COSV54024524; called by muse, mutect2, varscan2
- HIVEP1 | c.6901C>G p.Q2301E | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV65099981; called by muse, mutect2
- HIVEP2 | c.3873G>C p.K1291N | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV104376276, COSV50007903; called by muse, mutect2, varscan2
- HKDC1 | c.1571-1G>C p.X524_splice | Splice Site (SNP) | VAF 74/173 reads (43%) | catalogued as COSV63576215; called by muse, mutect2, varscan2
- HMCN1 | c.12171G>A p.M4057I | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as COSV54887971; called by muse, mutect2, varscan2
- HNRNPK | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); catalogued as COSV61088524, COSV61088811; called by muse, mutect2
- HOXA10 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52228383; called by muse, mutect2, varscan2
- HSPA13 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.566); catalogued as COSV53464961; called by muse, mutect2
- HSPG2 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV65930153; called by muse, mutect2, varscan2
- ICE1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV56821676; called by muse, mutect2, varscan2
- IFIT5 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.66); PolyPhen benign (0.127); catalogued as COSV65655360; called by muse, mutect2, varscan2
- IFIT5 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65655365; called by muse, mutect2, varscan2
- IFNA10 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 256/343 reads (75%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV53330758; called by muse, varscan2
- IFT80 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs374104108; called by muse, mutect2, varscan2
- IGSF1 | c.3978G>C p.Q1326H | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63836754; called by muse, mutect2, varscan2
- IQGAP3 | c.2064C>A p.F688L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV63250353; called by muse, mutect2, varscan2
- ITGA1 | c.2695-1G>A p.X899_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as rs1361447685, COSV99251452; called by muse, mutect2
- ITGA10 | c.1989G>C p.Q663H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV65196187, COSV65196542; called by muse, mutect2, varscan2
- ITPA | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV66261005; called by muse, mutect2, varscan2
- JPT2 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV50188641; called by muse, mutect2, varscan2
- KAT7 | c.164-1G>C p.X55_splice | Splice Site (SNP) | VAF 40/54 reads (74%) | catalogued as COSV52013665; called by muse, mutect2, varscan2
- KCNE3 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs547194943, COSV59551401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNS2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV99751176; called by muse, mutect2, varscan2
- KCTD10 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57326371; called by muse, mutect2, varscan2
- KCTD19 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV58571762; called by muse, mutect2, varscan2
- KDM6A | c.3505G>T p.V1169F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65038559; called by muse, mutect2, varscan2
- KIF17 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56117116; called by muse, mutect2, varscan2
- KLHL1 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100917048, COSV64777106; called by muse, mutect2, varscan2
- KLHL22 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100186049; called by muse, mutect2, varscan2
- KLK14 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50068145; called by muse, mutect2, varscan2
- KMT2C | c.13222G>C p.E4408Q | Missense Mutation (SNP) | VAF 69/98 reads (70%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as COSV51422466; called by muse, mutect2, varscan2
- KMT2D | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as COSV56423658, COSV56466666; called by muse, mutect2, varscan2
- KMT5B | c.2492C>G p.S831C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58564943; called by muse, mutect2, varscan2
- KNL1 | c.6090G>C p.E2030D (on ENST00000346991 / NM_170589.5; = p.E2004D on NM_144508.5) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV61152941; called by muse, mutect2, varscan2
- KRIT1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60667337; called by muse, mutect2, varscan2
- KRT20 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51424351; called by muse, mutect2, varscan2
- KRT9 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55852144, COSV55854056; called by muse, mutect2, varscan2
- L1TD1 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as COSV63133324; called by muse, mutect2, varscan2
- LAG3 | c.1170G>C p.Q390H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.135); catalogued as rs891464358, COSV52566875, COSV52568281; called by muse, mutect2, varscan2
- LAMA4 | c.4697G>T p.R1566L (on ENST00000230538 / NM_001105206.3; = p.R1559L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57894374; called by muse, mutect2, varscan2
- LAMB2 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as COSV59732075; called by muse, mutect2, varscan2
- LAMC1 | c.3312G>C p.Q1104H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV51135526, COSV51146254; called by muse, mutect2
- LCE2B | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1228200956, COSV64227539; called by muse, mutect2, varscan2
- LEMD3 | c.2024A>G p.D675G | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV57649324; called by muse, mutect2, varscan2
- LINGO1 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1413117169, COSV62436523; called by muse, mutect2, varscan2
- LRP12 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV99407793; called by muse, mutect2, varscan2
- LRP1B | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV101258010, COSV67200622; called by muse, mutect2
- LRRC14 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99467648; called by muse, mutect2, varscan2
- LRRC36 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52078831; called by muse, mutect2, varscan2
- LRRCC1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100835465; called by muse, mutect2
- LRTM1 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 11/154 reads (7%) | catalogued as COSV55516936, COSV55530779; called by muse, mutect2
- LTBP1 | c.4831G>C p.D1611H (on ENST00000404816 / NM_206943.4; = p.D1285H on NM_000627.4) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55377507, COSV55379794; called by muse, mutect2
- MACF1 | c.16417G>C p.E5473Q (on ENST00000372915; = p.E3406Q on NM_012090.5) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV57113578; called by muse, mutect2, varscan2
- MACF1 | c.20605C>T p.R6869C (on ENST00000372915; = p.R4914C on NM_012090.5) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV57113615; called by muse, mutect2, varscan2
- MAGEA4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs749725686, COSV52340763; called by muse, mutect2, varscan2
- MAGEB1 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs751987621, COSV66775509, COSV66775753; called by muse, mutect2, varscan2
- MAGEB18 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100305486, COSV100305495; called by muse, mutect2, varscan2
- MAGI3 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56832080, COSV56833114; called by muse, mutect2, varscan2
- MAK16 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV100659729; called by muse, mutect2, varscan2
- MAP2 | c.3628A>G p.I1210V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); catalogued as rs1388612630, COSV52285906; called by muse, mutect2, varscan2
- MAP2K2 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502388; called by muse, mutect2
- MAP3K3 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100675422, COSV100675548; called by muse, mutect2, varscan2
- MAP3K5 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100752872; called by muse, mutect2
- MAP3K7CL | c.371-1G>C p.X124_splice | Splice Site (SNP) | VAF 17/180 reads (9%) | catalogued as COSV54508411; called by muse, mutect2
- MAP6 | c.2441G>C p.*814Sext*22 | Nonstop Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100496708; called by muse, mutect2, varscan2
- MARF1 | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60021268; called by muse, mutect2, varscan2
- MAZ | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV50714363; called by muse, mutect2
- MCM9 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1251498776, COSV57647574; called by muse, mutect2, varscan2
- MCRS1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1187572691, COSV57790047; called by muse, mutect2, varscan2
- MED26 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); catalogued as COSV54659465; called by muse, mutect2, varscan2
- MET | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV104403507, COSV59259005; called by muse, mutect2
- METTL4 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs753372195, COSV55247508; called by muse, mutect2, varscan2
- MIA2 | c.2201A>G p.Y734C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs745606362, COSV54490989; called by muse, mutect2, varscan2
- MMP19 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.849); catalogued as COSV100491120; called by muse, mutect2
- MMP2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54599913; called by muse, mutect2, varscan2
- MMP3 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV55405537; called by muse, mutect2, varscan2
- MON1B | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV50245813; called by muse, mutect2, varscan2
- MPDZ | c.3093G>A p.M1031I | Missense Mutation (SNP) | VAF 113/142 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as rs1439482472, COSV59916336; called by muse, mutect2, varscan2
- MPEG1 | c.646A>T p.I216F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV57089409; called by muse, mutect2, varscan2
- MPP6 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV56035117; called by muse, mutect2, varscan2
- MRC2 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV57638076; called by muse, mutect2, varscan2
- MSH2 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1280971849, COSV51877360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTHFR | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV64877226; called by muse, mutect2, varscan2
- MUC16 | c.43060G>C p.E14354Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.828); catalogued as COSV66690795; called by muse, mutect2, varscan2
- MUC16 | c.21026C>G p.S7009C | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.263); catalogued as COSV67450400, COSV67455274; called by muse, mutect2, varscan2
- MUC17 | c.9470C>G p.S3157* | Nonsense Mutation (SNP) | VAF 58/342 reads (17%) | catalogued as COSV100073469; called by muse, mutect2, varscan2
- MUC17 | c.11144C>G p.S3715* | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | catalogued as COSV100073472; called by muse, mutect2, varscan2
- MUC20 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.084); catalogued as rs769738006, COSV100291327; called by mutect2, varscan2
- MYCBP2 | c.4938C>G p.F1646L (on ENST00000357337; = p.F1684L on NM_015057.5) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.878); catalogued as COSV62013624; called by muse, mutect2
- MYCBP2 | c.2536C>T p.P846S (on ENST00000357337; = p.P884S on NM_015057.5) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1409086619, COSV62013638; called by muse, mutect2, varscan2
- MYF6 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57351061; called by muse, mutect2, varscan2
- MYH13 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV52823652; called by muse, mutect2, varscan2
- MYH15 | c.4894G>C p.E1632Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56307012; called by muse, mutect2
- MYO7B | c.1851C>G p.F617L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.194); catalogued as COSV67346014; called by muse, mutect2, varscan2
- MYO9B | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV68278016; called by muse, mutect2, varscan2
- NACA | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV63268777; called by muse, mutect2, varscan2
- NBEA | c.6070C>G p.L2024V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59770444; called by muse, mutect2, varscan2
- NBPF11 | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs6675526, COSV65042989; called by muse, mutect2
- NCOR1 | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51968348; called by muse, mutect2, varscan2
- NCOR1 | c.2680G>C p.E894Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV51968381, COSV99246356; called by muse, mutect2
- NCOR1 | c.2419G>C p.E807Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV51965037, COSV51968402; called by muse, mutect2, varscan2
- NDEL1 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 129/165 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55325911; called by muse, mutect2, varscan2
- NDST3 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV56615688; called by muse, mutect2, varscan2
- NEMF | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100027686, COSV100028256; called by muse, mutect2, varscan2
- NFAT5 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63026102; called by muse, mutect2, varscan2
- NKAIN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs142309299; called by muse, mutect2, varscan2
- NKTR | c.4091G>C p.R1364T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51770553, COSV51775178; called by muse, mutect2, varscan2
- NLRP14 | c.2056G>C p.D686H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV55065458; called by muse, mutect2, varscan2
- NMT2 | c.1383G>C p.K461N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV65381856; called by muse, mutect2, varscan2
- NMT2 | c.1311G>C p.M437I | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV65381861; called by muse, mutect2, varscan2
- NNT | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 65/448 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52923881; called by muse, mutect2, varscan2
- NOMO1 | c.1809A>G p.E603= | Splice Region (SNP) | VAF 78/188 reads (41%) | catalogued as COSV55057758; called by muse, mutect2, varscan2
- NPC1L1 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56923638; called by muse, mutect2, varscan2
- NPY1R | c.183G>C p.L61F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56713897; called by muse, mutect2, varscan2
- NR1I2 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1480451898, COSV61977820; called by muse, mutect2, varscan2
- NR2F6 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs1370706715, COSV52243173; called by muse, mutect2, varscan2
- NRXN1 | c.3026T>C p.I1009T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV58443306; called by muse, mutect2, varscan2
- NT5C1A | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as COSV52494090, COSV99348469; called by muse, mutect2, varscan2
- NUDC | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.26); catalogued as COSV58324896; called by muse, mutect2, varscan2
- NUFIP2 | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV56602728; called by muse, mutect2
- NUP153 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50447425; called by muse, mutect2, varscan2
- NUP155 | c.3830C>G p.T1277S (on ENST00000231498 / NM_153485.3; = p.T1218S on NM_004298.4) | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51528374; called by muse, mutect2
- NWD1 | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60339782; called by muse, mutect2, varscan2
- OCA2 | c.1117-1G>C p.X373_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV62342039; called by muse, mutect2, varscan2
- OCRL | c.2501A>T p.N834I | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63980562; called by muse, mutect2, varscan2
- OGT | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65480138; called by muse, mutect2, varscan2
- OR10Z1 | c.936A>C p.K312N | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100778938, COSV100779023; called by muse, mutect2
- OR1N2 | c.287C>G p.S96W | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65460456; called by muse, mutect2
- OR1S1 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58706603, COSV58707945; called by muse, mutect2
- OR2D3 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs566650586, COSV58572747; called by muse, mutect2, varscan2
- OSBPL6 | c.1323G>C p.L441F | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51913872; called by muse, mutect2, varscan2
- P4HA3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV59041324; called by muse, mutect2
- PAIP1 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs930144885, COSV59085569; called by muse, mutect2
- PAK1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV53694925; called by muse, mutect2, varscan2
- PARP8 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV55858241; called by muse, mutect2, varscan2
- PAX7 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs745409821, COSV64749201; called by muse, mutect2, varscan2
- PCDH10 | c.957A>C p.E319D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52090431; called by muse, mutect2, varscan2
- PCDHA4 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV63540098; called by muse, mutect2, varscan2
- PCDHB15 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV50873676; called by muse, mutect2, varscan2
- PCDHGB4 | c.1142C>A p.T381N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV53920070; called by muse, mutect2, varscan2
- PCDHGB6 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs372007066, COSV99544185; called by muse, mutect2, varscan2
- PCNT | c.5551G>A p.D1851N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV64026611; called by muse, mutect2
- PCSK1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV60734503; called by muse, mutect2, varscan2
- PCSK2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52728915; called by muse, mutect2, varscan2
- PDCD6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs757962866, COSV99372805; called by mutect2, varscan2
- PDGFC | c.225G>C p.W75C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56846980; called by muse, mutect2, varscan2
- PDSS1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61015993; called by muse, mutect2, varscan2
- PEAK1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV56932814; called by muse, mutect2, varscan2
- PERP | c.137C>G p.S46W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV69827425; called by muse, mutect2, varscan2
- PEX19 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63619313; called by muse, mutect2, varscan2
- PF4V1 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.258); catalogued as COSV56953396; called by muse, mutect2, varscan2
- PIK3C2A | c.2308C>A p.Q770K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.412); catalogued as COSV56401462; called by mutect2, varscan2
- PIWIL1 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55344652; called by muse, mutect2, varscan2
- PKHD1 | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100582992, COSV61867307; called by muse, mutect2, varscan2
- PLB1 | c.3172T>C p.Y1058H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as COSV59822088; called by muse, mutect2, varscan2
- PLCE1 | c.6243G>C p.Q2081H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV53343370; called by muse, mutect2, varscan2
- PLCXD3 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 71/264 reads (27%) | catalogued as COSV100125797, COSV60610033; called by muse, varscan2
- PLEC | c.13121C>T p.S4374L (on ENST00000322810 / NM_201380.4; = p.S4264L on NM_000445.5) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs782530213, COSV59617748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA5 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54716681; called by muse, mutect2
- PLEKHH2 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as rs774767433, COSV56751276; called by muse, mutect2, varscan2
- PLIN3 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs757469368, COSV99701581; called by muse, mutect2, varscan2
- POLDIP3 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52808599; called by muse, mutect2, varscan2
- POLQ | c.2276C>G p.A759G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51748646; called by muse, mutect2
- POLR2B | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.217); catalogued as COSV58899463; called by muse, mutect2, varscan2
- POTEF | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100664948; called by mutect2, varscan2
- PPFIA1 | c.2991G>C p.L997F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54132987; called by muse, mutect2, varscan2
- PPP1R11 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV54992900; called by muse, mutect2
- PPP2R5B | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51209905; called by muse, mutect2, varscan2
- PPP3CC | c.249A>G p.V83= | Splice Region (SNP) | VAF 66/103 reads (64%) | catalogued as rs142254973; called by muse, mutect2, varscan2
- PPP6C | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV65207436; called by muse, mutect2, varscan2
- PPRC1 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as COSV53384153; called by muse, mutect2, varscan2
- PRDM5 | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53357865; called by muse, mutect2, varscan2
- PREX1 | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV64249798, COSV64252026; called by muse, mutect2, varscan2
- PROX1 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV54777263, COSV54782899; called by muse, mutect2, varscan2
- PROX1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV54777276; called by muse, mutect2, varscan2
- PRTFDC1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100196943; called by muse, varscan2
- PSMC5 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 32/238 reads (13%) | catalogued as COSV99856439; called by muse, mutect2, varscan2
- PSMC6 | c.275G>C p.R92T (on ENST00000612399; = p.R78T on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV71628640; called by muse, mutect2, varscan2
- PTCH1 | c.2763C>G p.I921M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as rs1564021738, COSV59468200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD1 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 120/240 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV65059537; called by muse, mutect2, varscan2
- PTCHD3 | c.2232C>G p.I744M | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71256470, COSV71256553, COSV71256834; called by muse, mutect2
- PTK7 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs146743539; called by muse, mutect2, varscan2
- PTK7 | c.1619-1G>A p.X540_splice | Splice Site (SNP) | VAF 24/170 reads (14%) | catalogued as COSV57847431; called by muse, mutect2, varscan2
- PTK7 | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as COSV100030617, COSV57847436; called by muse, mutect2
- PTPN21 | c.320C>A p.S107* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100161995; called by muse, mutect2, varscan2
- PTPRG | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55634309; called by muse, mutect2, varscan2
- PTPRK | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV63887366; called by muse, mutect2, varscan2
- PTPRR | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs753782110, COSV51727921, COSV51745234; called by muse, mutect2, varscan2
- PWWP3B | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV61798697; called by muse, mutect2
- PXK | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57087782, COSV57089470; called by muse, mutect2, varscan2
- PYGL | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773096764, COSV53585045; called by muse, varscan2
- PYROXD1 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs776874666, COSV53708332, COSV53708794; called by muse, mutect2, varscan2
- R3HDM1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51522537; called by muse, mutect2, varscan2
- RAB29 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1488232435, COSV52520857; called by muse, mutect2, varscan2
- RAB32 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62249005; called by muse, mutect2, varscan2
- RAB8A | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208176747, COSV56291292; called by muse, mutect2, varscan2
- RAI2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs763516658, COSV58963649; called by muse, mutect2, varscan2
- RASSF10 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as rs373322400; called by muse, mutect2, varscan2
- RB1CC1 | c.2988G>C p.Q996H | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV50244970; called by muse, mutect2, varscan2
- RBM17 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 47/105 reads (45%) | catalogued as COSV101159112; called by muse, mutect2, varscan2
- RBM6 | c.1695G>A p.V565= | Splice Region (SNP) | VAF 58/73 reads (79%) | catalogued as COSV56481220; called by muse, mutect2, varscan2
- RGS22 | c.1419C>G p.I473M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV62659525; called by muse, mutect2, varscan2
- RIBC1 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99394903; called by muse, mutect2, varscan2
- RIN3 | c.2232G>C p.Q744H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.194); catalogued as COSV53646679, COSV53649167; called by muse, mutect2, varscan2
- RNF180 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV56960980; called by muse, mutect2, varscan2
- RNF213 | c.12887C>G p.S4296C | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1349616641, COSV60393720; called by muse, mutect2, varscan2
- ROR1 | c.1865del p.L622* | Frame Shift Del (DEL) | VAF 46/106 reads (43%) | catalogued as COSV64287469; called by mutect2, pindel, varscan2
- RPS6KB1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 35/764 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs763367511, COSV56676056; called by muse, mutect2
- RPS6KB2 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57047875; called by muse, mutect2
- RSPH6A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55570814; called by muse, mutect2, varscan2
- RTEL1 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58891952; called by muse, mutect2, varscan2
- RTL9 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71825465; called by muse, mutect2, varscan2
- RTN3 | c.1318A>G p.M440V (on ENST00000377819 / NM_001265589.2; = p.M421V on NM_201428.3) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58027709; called by muse, mutect2, varscan2
- RUFY3 | c.1151T>A p.V384D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56912324; called by muse, varscan2
- RXFP4 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.115); catalogued as rs1241317541, COSV58142792; called by muse, varscan2
- SAP130 | c.3022C>G p.Q1008E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52095561; called by muse, mutect2, varscan2
- SCAF1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99882060; called by muse, mutect2
- SCAF4 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV54585319; called by muse, mutect2, varscan2
- SCAMP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs751039504, COSV56944296; called by muse, mutect2, varscan2
- SCAPER | c.3337G>C p.D1113H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57736898; called by muse, mutect2
- SCML2 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV52619708, COSV52620711; called by muse, mutect2, varscan2
- SCN3A | c.4862G>C p.R1621P | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51805583, COSV99328527; called by muse, mutect2, varscan2
- SCRIB | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782621145, COSV57584513; called by muse, mutect2, varscan2
- SDE2 | c.351A>T p.A117= | Splice Region (SNP) | VAF 17/87 reads (20%) | catalogued as COSV55250687; called by muse, varscan2
- SDE2 | c.351-1G>A p.X117_splice | Splice Site (SNP) | VAF 18/88 reads (20%) | catalogued as COSV55250707; called by muse, mutect2, varscan2
- SDK1 | c.1881G>C p.E627D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.469); catalogued as COSV67361743; called by muse, mutect2, varscan2
- SEC16A | c.4399C>G p.L1467V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51524210; called by muse, mutect2, varscan2
- SEC22A | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV59371579; called by muse, mutect2, varscan2
- SEC23IP | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV64831087; called by muse, mutect2, varscan2
- SEC61A1 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV54576529; called by muse, mutect2, varscan2
- SELENBP1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV64373211; called by muse, mutect2, varscan2
- SEMA6C | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176900236, COSV59001364; called by muse, mutect2, varscan2
- SERTAD1 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100781690; called by muse, mutect2, varscan2
- SETD4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59771669; called by muse, mutect2
- SEZ6L | c.2650C>A p.Q884K | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV50658495, COSV50660014; called by muse, mutect2
- SF3B3 | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV56786266, COSV56787590; called by muse, mutect2, varscan2
- SF3B3 | c.2062G>C p.D688H | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56786279, COSV56787502; called by muse, mutect2, varscan2
- SH3GL2 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.456); catalogued as COSV66049029; called by muse, varscan2
- SHPK | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.055); catalogued as rs753670176, COSV56648530; called by muse, mutect2, varscan2
- SIDT1 | c.2106G>C p.L702F | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs185416689, COSV53499606; called by muse, mutect2
- SIM1 | c.1293C>A p.D431E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs139715467, COSV53495466; called by muse, mutect2, varscan2
- SIRPA | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV61537482; called by muse, mutect2, varscan2
- SIRPB1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV53537514; called by muse, mutect2, varscan2
- SLA2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53410722; called by muse, mutect2, varscan2
- SLC15A2 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55196781; called by muse, mutect2, varscan2
- SLC18B1 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV51593395, COSV99259110; called by muse, mutect2, varscan2
- SLC20A1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV55610660; called by muse, mutect2
- SLC27A5 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 22/39 reads (56%) | catalogued as rs1189055667, COSV54021591, COSV99564406; called by muse, mutect2, varscan2
- SLC30A8 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV69969291; called by muse, mutect2, varscan2
- SLC4A5 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61026086; called by muse, mutect2, varscan2
- SLC7A5 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55363709, COSV55363906; called by muse, mutect2, varscan2
- SLC9C1 | c.1198-1G>C p.X400_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV59886766, COSV99998777; called by muse, mutect2, varscan2
- SLITRK5 | c.1847C>G p.S616* | Nonsense Mutation (SNP) | VAF 9/251 reads (4%) | catalogued as COSV100280797; called by muse, mutect2
- SMCP | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV64217619, COSV64217790; called by muse, mutect2
- SMURF1 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV63156564; called by muse, mutect2
- SMURF2 | c.1806G>C p.Q602H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV52313703; called by muse, mutect2, varscan2
- SNRK | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 71/92 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV56066977; called by muse, mutect2, varscan2
- SNRPD1 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55932464, COSV55933113; called by muse, mutect2, varscan2
- SP110 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs775810248, COSV51248290; called by muse, mutect2, varscan2
- SPACA7 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs779002404, COSV52098902; called by muse, mutect2
- SPART | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.662); catalogued as COSV100768828, COSV62084335; called by muse, mutect2, varscan2
- SPEN | c.7933C>G p.Q2645E | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV65359675; called by muse, mutect2, varscan2
- SPHKAP | c.3425G>C p.R1142T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60868248, COSV60873012; called by muse, mutect2, varscan2
- SPIRE2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV65554902; called by muse, mutect2, varscan2
- SRRM2 | c.1928G>C p.R643T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV57070686; called by muse, mutect2, varscan2
- SRSF12 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV71683652; called by muse, mutect2, varscan2
- STAB2 | c.7486G>C p.E2496Q | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV66334338, COSV66336904; called by muse, mutect2, varscan2
- STAG1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV52605466; called by muse, mutect2, varscan2
- STAU1 | c.1078C>T p.Q360* (on ENST00000371856 / NM_001319135.1; = p.Q279* on NM_004602.3) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100574380; called by muse, mutect2, varscan2
- STK32A | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60416817; called by muse, mutect2, varscan2
- STON1 | c.610A>C p.K204Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV59128287; called by muse, mutect2, varscan2
- STRA6 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60585167; called by muse, mutect2
- STRBP | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62117458; called by muse, mutect2, varscan2
- STX12 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV64249130; called by muse, mutect2, varscan2
- SULF1 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52677432; called by muse, mutect2, varscan2
- SULF2 | c.2373G>C p.L791= | Splice Region (SNP) | VAF 12/124 reads (10%) | catalogued as COSV63414997; called by muse, mutect2
- SUPT20HL2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 94/171 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs747276547; called by muse, mutect2, varscan2
- SYMPK | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs1023200427, COSV55610488; called by muse, mutect2, varscan2
- SYN3 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100249144; called by muse, mutect2
- SYNJ1 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100449338; called by muse, mutect2
- TAF1 | c.3726G>C p.L1242= (on ENST00000373790 / NM_138923.4; = p.L1263= on NM_004606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99335866; called by muse, mutect2
- TAGAP | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1217339653, COSV57850461; called by muse, mutect2, varscan2
- TANC2 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757851333, COSV67332369; called by muse, varscan2
- TBC1D16 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs972262859, COSV60476608; called by muse, mutect2, varscan2
- TBC1D25 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as COSV65123426; called by muse, mutect2, varscan2
- TCHH | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV64273811; called by muse, mutect2
- TDRP | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1186356158, COSV60705271; called by muse, mutect2
- TECTA | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV50696139; called by muse, mutect2, varscan2
- TENM1 | c.3025G>C p.E1009Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64428238; called by muse, mutect2, varscan2
- TENT4A | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50094828; called by muse, mutect2
- TGM4 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs774638487, COSV56093317; called by muse, varscan2
- TGM4 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as rs377297402, COSV56093322; called by muse, varscan2
- TINF2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs746984199, COSV57468441; called by muse, mutect2, varscan2
- TJP3 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV99516123; called by muse, mutect2, varscan2
- TLR10 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV58299618; called by muse, mutect2, varscan2
- TLR10 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV58299558; called by muse, mutect2, varscan2
- TMC1 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV52771750; called by muse, mutect2
- TMTC2 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV58263520; called by muse, mutect2, varscan2
- TNFRSF13C | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as rs1315010086, COSV52169430; called by muse, mutect2, varscan2
- TNXB | c.3796C>G p.P1266A (on ENST00000647633; = p.P1019A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV100926376; called by muse, mutect2
- TP53BP2 | c.1415C>T p.S472F (on ENST00000343537 / NM_001031685.3; = p.S343F on NM_005426.2) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV59067265; called by muse, mutect2, varscan2
- TPRN | c.1487G>C p.R496P | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs753923691, COSV58806872; called by muse, mutect2, varscan2
- TPST1 | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV59175842; called by mutect2, varscan2
- TRAF4 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52217979; called by muse, mutect2
- TRANK1 | c.5093C>T p.T1698I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57145396; called by muse, mutect2, varscan2
- TRBV28 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1320251465; called by muse, mutect2, varscan2
- TRH | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV57014744; called by muse, mutect2, varscan2
- TRIM42 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV53881155; called by muse, mutect2
- TRIM42 | c.1869G>C p.W623C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53881165; called by muse, mutect2, varscan2
- TRIO | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV60080246; called by muse, mutect2
- TRIO | c.6435G>C p.M2145I | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV60080253; called by muse, mutect2, varscan2
- TRIP4 | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99974619; called by muse, mutect2
- TRMT12 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV60776742; called by muse, mutect2, varscan2
- TRMT5 | c.1000A>C p.K334Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV54203162; called by muse, mutect2, varscan2
- TRMT5 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1273799647, COSV50781732; called by muse, mutect2, varscan2
- TRPC4 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV58995117; called by muse, mutect2
- TRPC5 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53286853; called by muse, mutect2, varscan2
- TTN | c.87598G>C p.E29200Q (on ENST00000591111; = p.E21776Q on NM_003319.4) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | PolyPhen probably damaging (0.93); catalogued as rs765241194, COSV59959918; called by muse, mutect2, varscan2
- TTN | c.34534C>G p.P11512A (on ENST00000591111; = p.P10585A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/131 reads (30%) | PolyPhen benign (0.023); catalogued as COSV59959977; called by muse, mutect2, varscan2
- TUBA1C | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99988805; called by muse, mutect2, varscan2
- TUBA3C | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV67139031; called by muse, mutect2, varscan2
- UBC | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV60058901; called by muse, varscan2
- UBE2M | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV53396619; called by muse, mutect2, varscan2
- UBR5 | c.6286G>C p.E2096Q | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55283320, COSV55286509; called by muse, mutect2
- UGGT2 | c.531_534del p.N177Kfs*7 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs751349526; called by pindel, varscan2
- UGT1A10 | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60834900; called by muse, mutect2, varscan2
- UGT2B17 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 78/100 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58501140; called by muse, mutect2, varscan2
- UGT8 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60417031; called by muse, mutect2, varscan2
- UNC13C | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs541524342, COSV52855564; called by muse, mutect2, varscan2
- USH1C | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as rs769420899, COSV50014911, COSV99140070; called by muse, mutect2, varscan2
- USH2A | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV56347625, COSV56347813; called by muse, mutect2, varscan2
- USP31 | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54850719; called by mutect2, varscan2
- USP34 | c.8071C>A p.L2691I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV68399690; called by muse, mutect2, varscan2
- USP34 | c.7986G>C p.Q2662H | Missense Mutation (SNP) | VAF 186/406 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV68399698; called by muse, mutect2, varscan2
- USP54 | c.2668C>T p.Q890* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100357411; called by muse, mutect2, varscan2
- USPL1 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs377233644; called by muse, mutect2, varscan2
- UTP3 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV54660821; called by muse, mutect2, varscan2
- UTP6 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV55572317; called by muse, mutect2
- VPS13D | c.4177G>A p.G1393R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV50629239; called by muse, mutect2, varscan2
- VSIG8 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV63652591; called by muse, mutect2
- WARS1 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100690188; called by muse, mutect2, varscan2
- WDHD1 | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100777589; called by muse, mutect2, varscan2
- WIPF2 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60272991, COSV60273489; called by muse, mutect2, varscan2
- WWOX | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372362643; called by muse, mutect2, varscan2
- XKR7 | c.1585C>G p.R529G | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143869401, COSV73813040; called by muse, mutect2, varscan2
- XPO5 | c.1588G>C p.D530H | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV54828567; called by muse, mutect2, varscan2
- XPOT | c.1025A>G p.D342G | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV60344547; called by muse, mutect2, varscan2
- XRN1 | c.2939C>A p.S980* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV53817905, COSV99378077; called by muse, mutect2, varscan2
- YME1L1 | c.701C>G p.S234* (on ENST00000326799 / NM_139312.3; = p.S177* on NM_014263.4) | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | catalogued as COSV100463707, COSV58758490; called by muse, mutect2, varscan2
- ZBTB5 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV57039358; called by muse, mutect2, varscan2
- ZC3H12D | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66323556, COSV66324125; called by muse, mutect2, varscan2
- ZFP14 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV54201668, COSV54203680; called by muse, mutect2, varscan2
- ZFP90 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV68050766; called by muse, mutect2, varscan2
- ZFPM2 | c.3202C>T p.Q1068* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV101023237; called by muse, mutect2, varscan2
- ZFR | c.1619T>G p.V540G | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV54051661; called by muse, mutect2
- ZNF14 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV59848825; called by muse, mutect2, varscan2
- ZNF235 | c.1112G>C p.G371A | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52155739; called by muse, mutect2, varscan2
- ZNF285 | c.1264C>G p.H422D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1301046424, COSV58408424, COSV58411120; called by muse, mutect2, varscan2
- ZNF292 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60537166; called by muse, mutect2, varscan2
- ZNF296 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55515198; called by muse, mutect2, varscan2
- ZNF320 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV67087829; called by muse, mutect2, varscan2
- ZNF34 | c.1542G>C p.Q514H | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV58638612; called by muse, mutect2, varscan2
- ZNF354A | c.1509C>G p.F503L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59982826; called by muse, mutect2, varscan2
- ZNF382 | c.1089G>C p.Q363H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as COSV53086967; called by muse, mutect2, varscan2
- ZNF394 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV58742354; called by muse, mutect2, varscan2
- ZNF404 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60986825, COSV60987502; called by muse, mutect2, varscan2
- ZNF451 | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV62597147; called by muse, mutect2, varscan2
- ZNF486 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV58718142, COSV58719962; called by muse, mutect2, varscan2
- ZNF560 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV56866754; called by muse, mutect2
- ZNF569 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1367912384, COSV57594327; called by muse, mutect2, varscan2
- ZNF585B | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57214907; called by muse, mutect2
- ZNF620 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV58820194; called by muse, mutect2, varscan2
- ZNF667 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV52632517; called by muse, mutect2, varscan2
- ZNF677 | c.366G>C p.L122F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV61719799; called by muse, mutect2, varscan2
- ZNF701 | c.505G>A p.E169K (on ENST00000301093; = p.E103K on NM_018260.3) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as COSV56523501, COSV56523843; called by muse, mutect2
- ZNF773 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV56588062; called by muse, mutect2, varscan2
- ZNF778 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1228577894, COSV60600876; called by muse, mutect2, varscan2
- ZNF80 | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV57360282; called by muse, mutect2, varscan2
- ZNF823 | c.1799G>C p.R600T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.983); catalogued as COSV100362501, COSV57872242; called by muse, mutect2
- ZNF835 | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV73379328; called by muse, varscan2
- ZNF85 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1348710230, COSV56021299, COSV56022002; called by muse, mutect2, varscan2
- ZNF862 | c.1941C>G p.F647L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV56222499, COSV56223362; called by muse, mutect2, varscan2
- ZPBP | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV50423611; called by muse, mutect2, varscan2
- ZWILCH | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs769995701, COSV57178993; called by muse, mutect2, varscan2
- ADAM29 | c.1527del p.F509Lfs*16 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- AKAP13 | c.6383_6385del p.X2128_splice (on ENST00000394518 / NM_007200.5; = p.X2132_splice on NM_006738.6) | Splice Site (DEL) | VAF 22/160 reads (14%) | called by pindel, varscan2
- EXD3 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2
- EYS | c.1343dup p.L448Ffs*25 | Frame Shift Ins (INS) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- HERC2 | c.3450_3467del p.L1151_G1156del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- ITGB8 | c.1160_1173del p.E387Gfs*11 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | called by mutect2, pindel, varscan2
- MARK3 | c.872_877dup p.N291_P292dup | In Frame Ins (INS) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- MRC1 | c.2406T>A p.D802E | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- POLR2A | c.2820G>C p.K940N | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.53); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PRAMEF19 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC9 | c.556del p.S186Pfs*30 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, varscan2
- TRAV10 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- AARS2 | c.1350G>A p.L450= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs376105475; called by muse, mutect2, varscan2
- ABCA3 | c.4272G>T p.T1424= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV57051392, COSV57053735; called by muse, mutect2, varscan2
- ABCA5 | c.4119G>A p.L1373= | Silent (SNP) | VAF 65/82 reads (79%) | catalogued as COSV67016210; called by muse, mutect2, varscan2
- ABCC6 | c.4212G>A p.V1404= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99228859, COSV99229090; called by muse, mutect2, varscan2
- ADAM22 | c.216G>C p.T72= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV55973136, COSV99716640; called by muse, mutect2, varscan2
- ADCY9 | c.2736C>T p.F912= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs375855314; called by muse, varscan2
- ADGRE1 | c.2232G>A p.L744= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as COSV51673805; called by muse, mutect2
- AGL | c.3525C>G p.L1175= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as COSV54050497; called by muse, mutect2, varscan2
- AKAP6 | c.3972C>T p.L1324= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs753210843, COSV55209002, COSV99801840; called by muse, mutect2, varscan2
- ANAPC4 | c.528C>T p.L176= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs149911152; called by muse, mutect2, varscan2
- AQP11 | c.126G>T p.P42= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs182849204, COSV57992188, COSV99047009; called by muse, mutect2, varscan2
- ARHGEF6 | c.132G>C p.L44= | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as COSV51688890; called by muse, mutect2, varscan2
- ARPC5 | c.6G>T p.S2= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as COSV54171211, COSV54172992; called by muse, mutect2, varscan2
- ASPH | c.546G>A p.E182= | Silent (SNP) | VAF 39/526 reads (7%) | catalogued as rs777861394, COSV62858495, COSV62858754; called by muse, mutect2
- ATP11C | c.528C>T p.V176= | Silent (SNP) | VAF 58/243 reads (24%) | catalogued as COSV59561092; called by muse, mutect2, varscan2
- ATP13A1 | c.1959G>A p.V653= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1238963759, COSV99366200; called by muse, mutect2
- ATP2C1 | c.336C>T p.I112= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs745397500, COSV60754640; called by muse, mutect2, varscan2
- AUNIP | c.207C>T p.F69= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs751429847, COSV65352662; called by muse, mutect2, varscan2
- AZU1 | c.702C>A p.L234= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52140575, COSV52141518; called by muse, varscan2
- BICDL1 | c.1530G>T p.L510= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV57492902, COSV99985845; called by muse, mutect2, varscan2
- BOK | c.525C>T p.L175= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV59192264, COSV59193016; called by muse, mutect2, varscan2
- CACNA1I | c.3582C>T p.I1194= | Silent (SNP) | VAF 62/120 reads (52%) | catalogued as rs921389942, COSV60803972, COSV60807173; called by muse, mutect2, varscan2
- CALCR | c.133C>A p.R45= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as COSV64006530, COSV64006861; called by muse, mutect2
- CAPN6 | c.1725C>T p.D575= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV60694321; called by muse, mutect2, varscan2
- CAPN6 | c.1488A>G p.E496= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as COSV60694331; called by muse, mutect2, varscan2
- CCDC114 | c.1782G>C p.S594= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs568161381, COSV59555967; called by muse, mutect2, varscan2
- CDH16 | c.1725C>T p.I575= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV55335771; called by muse, mutect2, varscan2
- CDH18 | c.1527C>T p.I509= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV56911098; called by muse, mutect2
- CDKL5 | c.159C>G p.V53= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV66110647; called by muse, mutect2, varscan2
- CEACAM20 | c.1678C>T p.L560= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs748031361, COSV57601173; called by muse, mutect2, varscan2
- CEP152 | c.4446C>T p.L1482= (on ENST00000380950 / NM_001194998.2; = p.L1426= on NM_014985.4) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV57858049; called by muse, mutect2, varscan2
- CEP250 | c.4170G>C p.L1390= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100698944; called by muse, mutect2
- CHD8 | c.6342C>G p.L2114= (on ENST00000646647 / NM_001170629.2; = p.L1835= on NM_020920.4) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV63036597; called by muse, mutect2, varscan2
- CHRNB2 | c.1389C>T p.L463= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV63807920; called by muse, mutect2, varscan2
- CHTF18 | c.2295C>G p.L765= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs780566524, COSV50210265; called by muse, mutect2, varscan2
- CPSF7 | c.702G>A p.L234= (on ENST00000394888 / NM_001136040.4; = p.L277= on NM_024811.4) | Silent (SNP) | VAF 47/73 reads (64%) | catalogued as COSV61210644; called by muse, mutect2, varscan2
- CROT | c.1593C>G p.S531= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV58973413; called by muse, mutect2, varscan2
- CYP4F8 | c.807C>G p.A269= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV100358128; called by muse, mutect2, varscan2
- DDX24 | c.2364G>A p.L788= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs1472385973, COSV52572990; called by muse, mutect2, varscan2
- DDX52 | c.714G>C p.L238= | Silent (SNP) | VAF 73/253 reads (29%) | called by muse, mutect2, varscan2
- DECR1 | c.24C>T p.F8= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV55167955, COSV55168153; called by muse, mutect2, varscan2
- DLC1 | c.3639A>G p.A1213= (on ENST00000276297 / NM_001348081.2; = p.A776= on NM_006094.5) | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV52296548; called by muse, mutect2, varscan2
- DMTF1 | c.609G>C p.L203= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1263145116, COSV58684063; called by muse, mutect2
- DNAH3 | c.2385G>A p.L795= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV54511833; called by muse, mutect2, varscan2
- DNAH7 | c.6819C>T p.F2273= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV56757530; called by muse, mutect2, varscan2
- DNAJC16 | c.2199C>A p.L733= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV65435739; called by muse, mutect2, varscan2
- DZIP1 | c.453G>C p.L151= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV61264667; called by muse, mutect2, varscan2
- EEF2 | c.300C>A p.I100= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV58578932; called by muse, mutect2, varscan2
- ERGIC2 | c.162A>G p.V54= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs1485067548, COSV64111306; called by muse, mutect2, varscan2
- ERN2 | c.630C>T p.L210= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV56832449; called by mutect2, varscan2
- FAM120A | c.2316C>T p.L772= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV52903037; called by muse, mutect2, varscan2
- FANCB | c.2520G>A p.L840= | Silent (SNP) | VAF 70/264 reads (27%) | catalogued as rs752337343, COSV60759219; called by muse, mutect2, varscan2
- FAT3 | c.10240C>T p.L3414= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV53092055; called by muse, mutect2, varscan2
- FAT3 | c.12726G>A p.Q4242= | Silent (SNP) | VAF 9/172 reads (5%) | catalogued as COSV53092070; called by muse, mutect2
- FBRS | c.240G>A p.L80= (on ENST00000287468; = p.L600= on NM_001105079.3) | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV54915290; called by muse, mutect2
- FBXO10 | c.1681C>T p.L561= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV52832158, COSV52835825; called by muse, mutect2, varscan2
- FBXO10 | c.1680C>T p.I560= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs780405263, COSV52832168; called by muse, mutect2, varscan2
- FEM1A | c.843G>A p.L281= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1005467505, COSV54163289; called by muse, mutect2, varscan2
- FIGN | c.1971G>T p.A657= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100292988, COSV60764662; called by muse, mutect2, varscan2
- FNDC3B | c.1083C>G p.S361= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs756597691, COSV100394220, COSV61039637; called by muse, mutect2, varscan2
- FRMD5 | c.1437G>A p.L479= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV68721015; called by muse, mutect2, varscan2
- FRS3 | c.291C>T p.I97= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as COSV52484470; called by muse, varscan2
- FSCN1 | c.528C>G p.L176= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV61016985, COSV61017190; called by muse, mutect2, varscan2
- FYB1 | c.576C>G p.L192= | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as COSV60943496; called by muse, varscan2
- GPR31 | c.123C>T p.F41= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs780348906, COSV64761259; called by muse, mutect2, varscan2
- HAS3 | c.942C>T p.F314= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs768983599, COSV54706258; called by muse, mutect2, varscan2
- HCAR2 | c.765C>T p.F255= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs957080877, COSV61024633; called by muse, mutect2, varscan2
- HENMT1 | c.684C>T p.I228= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV64230033; called by muse, mutect2, varscan2
- HMCN1 | c.8565A>C p.G2855= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54887962; called by muse, mutect2, varscan2
- HTR3E | c.1041C>G p.L347= (on ENST00000415389 / NM_001256613.1; = p.L362= on NM_182589.2) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV58946213; called by muse, mutect2, varscan2
- IFNL3 | c.399C>T p.L133= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV69829864; called by muse, mutect2, varscan2
- IGHA2 | c.198G>A p.T66= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs782814394; called by muse, mutect2, varscan2
- IGKJ4 | c.12C>T p.G4= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs181159708; called by muse, mutect2, varscan2
- ING1 | c.405C>T p.F135= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1031961929, COSV58168075; called by muse, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2, varscan2
- ITGB2 | c.1821G>A p.L607= (on ENST00000302347; = p.L583= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV56608979; called by muse, mutect2, varscan2
- KANK3 | c.1353G>A p.K451= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58359509; called by muse, mutect2, varscan2
- KAT2B | c.282C>T p.L94= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs1407398623, COSV55426620; called by muse, mutect2, varscan2
- KCNG4 | c.1329C>T p.I443= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV57583188; called by muse, mutect2
- KIAA0100 | c.4062C>A p.V1354= | Silent (SNP) | VAF 63/151 reads (42%) | catalogued as COSV66491479; called by muse, mutect2, varscan2
- KIAA0753 | c.273C>A p.V91= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV63817047; called by muse, mutect2, varscan2
- KL | c.2517C>G p.L839= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV66308275; called by muse, mutect2, varscan2
- KLHL9 | c.571C>T p.L191= | Silent (SNP) | VAF 41/49 reads (84%) | catalogued as COSV62921338; called by muse, mutect2, varscan2
- KLRC2 | c.225C>G p.V75= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as rs755968670, COSV101122769, COSV67899623; called by muse, mutect2, varscan2
- KRI1 | c.1428G>A p.K476= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100470505, COSV57264103; called by muse, mutect2, varscan2
- L3MBTL4 | c.192C>G p.V64= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53117122, COSV53131760; called by muse, mutect2, varscan2
- LRRC7 | c.2379T>A p.P793= (on ENST00000651989 / NM_001370785.2; = p.P760= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV50430751; called by muse, mutect2, varscan2
- MAPKAP1 | c.618G>C p.L206= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV56365970; called by muse, mutect2, varscan2
- MAST1 | c.4158C>T p.V1386= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs578030752, COSV52243775; called by muse, mutect2, varscan2
- MBD2 | c.561C>T p.F187= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV56500526; called by muse, mutect2, varscan2
- MDH2 | c.204G>C p.L68= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV59883959; called by muse, mutect2
- MED19 | c.288C>T p.F96= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV54705858; called by muse, mutect2, varscan2
- MINAR1 | c.2088C>T p.V696= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV59581754; called by muse, mutect2, varscan2
- MMS22L | c.2007G>A p.L669= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs1350982975, COSV51519081; called by muse, mutect2, varscan2
- MRPL37 | c.747G>A p.K249= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV60321364; called by muse, mutect2, varscan2
- MTOR | c.846G>C p.L282= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV63869550; called by muse, mutect2, varscan2
- MXRA5 | c.1929C>T p.V643= | Silent (SNP) | VAF 83/144 reads (58%) | catalogued as COSV54229720; called by muse, mutect2, varscan2
- MYH7B | c.1083C>A p.V361= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV53417921; called by muse, mutect2, varscan2
- MYO18A | c.6120G>A p.L2040= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as COSV62864454; called by muse, mutect2, varscan2
- NAF1 | c.1011C>G p.L337= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV56803754; called by muse, mutect2
- NDUFA4 | c.18C>A p.I6= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV60011852; called by muse, mutect2
- NEO1 | c.2478G>C p.V826= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV56069231; called by muse, mutect2, varscan2
- NLRP5 | c.1395C>T p.L465= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs763552323, COSV66763201; called by muse, mutect2, varscan2
- NT5C1A | c.489C>G p.L163= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV52493819, COSV52494177; called by muse, mutect2, varscan2
- NTRK3 | c.426C>G p.L142= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV58115348; called by muse, mutect2, varscan2
- NUP155 | c.813C>T p.F271= (on ENST00000231498 / NM_153485.3; = p.F212= on NM_004298.4) | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as COSV51528393; called by muse, mutect2, varscan2
- NUP98 | c.4014C>G p.L1338= (on ENST00000359171 / NM_001365126.1; = p.L1321= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV61430367; called by muse, mutect2, varscan2
- OPA1 | c.513G>A p.K171= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV62479648; called by muse, mutect2, varscan2
- OR4D9 | c.246G>C p.L82= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV100259690, COSV61434381; called by muse, mutect2, varscan2
- OR7A17 | c.735C>G p.L245= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV59414017; called by muse, mutect2, varscan2
- OR7C1 | c.369C>T p.F123= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV50182847; called by muse, mutect2, varscan2
- P3H2 | c.1044C>T p.Y348= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV60019824; called by muse, mutect2, varscan2
- PCLO | c.3105T>C p.S1035= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV61624498; called by muse, mutect2, varscan2
- PGLYRP2 | c.78C>G p.L26= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV52992426; called by muse, mutect2
- PIK3CG | c.1089C>G p.V363= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV63246979; called by muse, mutect2, varscan2
- PKHD1 | c.9199C>T p.L3067= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as COSV61867289; called by muse, mutect2, varscan2
- PLB1 | c.3501T>C p.N1167= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV59822107; called by muse, varscan2
- PLEC | c.13377C>T p.I4459= (on ENST00000322810 / NM_201380.4; = p.I4349= on NM_000445.5) | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as rs201042249; called by muse, mutect2, varscan2
- PLPP6 | c.864C>G p.L288= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV56304852; called by muse, mutect2, varscan2
- PLXNA3 | c.5481C>T p.L1827= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV63753568; called by muse, mutect2, varscan2
- POM121L12 | c.786C>T p.S262= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1008648432, COSV101374808, COSV68692571; called by muse, mutect2, varscan2
- POU2F2 | c.930C>T p.F310= (on ENST00000526816 / NM_001207025.3; = p.F294= on NM_002698.5) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV60760939; called by muse, mutect2, varscan2
- PRAMEF15 | c.114C>T p.F38= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.1053C>G p.L351= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs376650368, COSV53573681; called by muse, mutect2, varscan2
- PRKCG | c.654G>A p.T218= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs961741139, COSV54725837; called by muse, mutect2, varscan2
- PRSS12 | c.951C>T p.I317= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV56605200; called by muse, mutect2, varscan2
- PSG6 | c.12C>T p.L4= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as COSV51831529; called by muse, mutect2, varscan2
- PSMB10 | c.228C>T p.I76= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as rs1298241601, COSV50452394; called by muse, mutect2, varscan2
- PTCH2 | c.2181G>C p.L727= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1377491071, COSV64710425; called by muse, mutect2, varscan2
- PTOV1 | c.1008G>A p.L336= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs1422434857, COSV55587088; called by muse, mutect2, varscan2
- PTPRK | c.1431G>A p.E477= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs766470450, COSV63894068; called by muse, mutect2, varscan2
- PUF60 | c.474C>T p.I158= (on ENST00000526683 / NM_001362896.2; = p.I141= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs924417716, COSV57584527; called by muse, mutect2, varscan2
- PXDN | c.1452G>T p.S484= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs80053278, COSV53229892; called by muse, mutect2, varscan2
- PYHIN1 | c.675A>G p.V225= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV63721924; called by muse, mutect2, varscan2
- RARS2 | c.447C>T p.I149= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV65760544; called by muse, mutect2
- RBM6 | c.1962G>A p.E654= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99805486; called by muse, varscan2
- RELN | c.2025C>G p.L675= | Silent (SNP) | VAF 47/65 reads (72%) | catalogued as COSV58985537, COSV58993200; called by muse, mutect2, varscan2
- RIPOR3 | c.408C>T p.I136= | Silent (SNP) | VAF 71/130 reads (55%) | catalogued as COSV50386801; called by muse, mutect2, varscan2
- RNF216 | c.678G>C p.G226= (on ENST00000425013 / NM_207116.3; = p.G283= on NM_207111.4) | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV66289886; called by muse, mutect2
- RPRML | c.255C>T p.F85= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV59262609; called by muse, mutect2
- RPS6KB1 | c.462C>T p.F154= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as rs1198785001, COSV56676048; called by muse, mutect2
- RXFP4 | c.72G>A p.L24= | Silent (SNP) | VAF 76/145 reads (52%) | catalogued as rs1008272911, COSV64163779; called by muse, mutect2, varscan2
- RXFP4 | c.594G>A p.R198= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV58142799; called by muse, varscan2
72 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 26 other) are not listed here.
